PECGS case C083-000082 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/92eabe9d-d251-4b85-af6f-579456169f8b

Demographics
Sex at birth: male; Age at index: 66 years; Year of birth: 1954; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Descending colon; Age at diagnosis: 66.4 years (24,253 days); AJCC pathologic stage: Stage IIIB; Progression or recurrence: no.

Other clinical attributes
- BMI: 26.31.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 22; Alcohol history: No.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000082_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000082_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
